MMRF case MMRF_1505 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c5111085-2ba4-4d1f-9e96-e7e7f39459a7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.7 years (22,885 days); ISS stage: III; Days to last known disease status: 162 days; Days to last follow up: 162 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 15 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 36 days; Days to treatment end: 127 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 1): M Protein 6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 33.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 45.4 mg/dL; Immunoglobulin G 83.5 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 5.6 µg/mL; Lactate Dehydrogenase 9.49 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 12.7 g/dL; Glucose 6.33 mmol/L; C-Reactive Protein 2.7 mg/dL.
- Day 85 (ECOG 1): M Protein 2.44 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Immunoglobulin G 24.5 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 6.88 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 8.5 g/dL; Glucose 7.7 mmol/L.
- Day 162 (ECOG 1): M Protein 2.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 43.4 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 12 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 14 ×10⁹/L; Absolute Neutrophil 11.1 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 9.5 g/dL; Glucose 5.34 mmol/L.

Other clinical attributes
- Day -2: Weight: 106 kg; Height: 185 cm.

Biospecimens (2 samples)
- Sample MMRF_1505_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1505_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
